Surgical pathology report (de-identified scan), TCGA case TCGA-DK-AA76, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-AA76-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient Name:

Med. Rec. #:

DOB: (Age)

Gender: F

Ref. Physician:

Patient Address:

Location:

Service: Urology

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

female with hematuria and bladder lesions seen on cystoscopy

Specimens Submitted:

1: Tumor of anterior bladder wall, TURB

DIAGNOSIS:

1. Tumor of anterior bladder wall, TURB

Tumor Type:

Invasive urothelial carcinoma, NOS

Histologic Grade:

High grade

Pattern of growth of the non-invasive component:

Papillary

Local Invasion:

Muscularis propria

Vascular Invasion:

Not identified

ICD O-3

Carcinoma, urothelial NOS
8120/3
Site: Bladder, anterior wall
C67.3
W4130/14

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received in Hanks solution and placed in formalin. It is labeled "tumor of anterior bladder wall", and consists of a 2.4 x 1.5 x 0.6 cm aggregate of multiple portions of pink-tan shaggy rubbery tissue. A portion is submitted for TPS. The remaining tissues entirely submitted.

Summary sections:

- undesignated

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Summary of Sections:

Part 1: Tumor of anterior bladder wall, TURB

Blocks	Block Designation	PCs
3		11

Source: NCI Genomic Data Commons file 7fc5b66b-ffcc-4411-9827-dbbeb4b49bb2 (TCGA-DK-AA76.3271070D-5B10-4243-BEE5-AFDD60B7CDDA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).